Somatic mutation profile of tumor specimen TCGA-SR-A6MZ-01A (aliquot TCGA-SR-A6MZ-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.0 years (16,802 days).
Specimen TCGA-SR-A6MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ff50076-4d13-4575-8f4d-a96be8feb590.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MZ-10A (Blood Derived Normal), aliquot TCGA-SR-A6MZ-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cee0f13c-1dfd-488b-b60f-aeb629ee9754

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs534252499; called by muse, mutect2, varscan2
- DDI2 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.406); catalogued as COSV60781540; called by muse, mutect2, varscan2
- EPHB2 | c.1848T>C p.I616= (on ENST00000400191 / NM_001309193.2; = p.I617= on NM_004442.7) | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2571C>T p.A857= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs747456374; called by muse, varscan2
- PTCHD3 | c.1104A>G p.T368= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
